Gene-level copy-number profile of tumor specimen TCGA-M8-A5N4-01A from TCGA case TCGA-M8-A5N4, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIA; Tumor grade: G2.
Specimen TCGA-M8-A5N4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.0861c063-0949-4121-869b-5e179bdd1535.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-M8-A5N4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/112eb542-b76a-42da-b8a4-2d9e38fabb6e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 27; copy number 1: 8,813; copy number 2: 50,075; copy number 3: 902.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-M8-A5N4-01A-11D-A26H-01): tumor purity 0.22, ploidy 3.46, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:231,814,982–231,815,186, 1 gene: AL136171.1.
- chr2:197,569–209,892, 1 gene: AC079779.1.
- chr3:11,745–54,346, 2 genes: LINC01986, AC066595.1.
- chr4:76,894,152–76,898,144, 1 gene (within-gene range 0–2): SOWAHB.
- chr4:135,565,117–135,567,157, 1 gene: TARS2P1.
- chr5:120,245,448–120,410,969, 3 genes: AC008574.1, RNU6-718P, AC113418.1.
- chr8:9,287,472–9,287,578, 1 gene: RNU6-1151P.
- chr9:87,724,051–87,786,884, 3 genes: CTSL, AL160279.1, CTSL3P.
- chr11:135,061,781–135,075,908, 1 gene: LINC02684.
- chr14:106,850,885–106,875,071, 6 genes: MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV4-80, IGHV7-81.
- chr18:49,560,699–49,599,185, 1 gene: LIPG.
- chr18:80,157,232–80,247,514, 1 gene (within-gene range 0–1): PARD6G.
- chr20:4,023,917–4,075,165, 3 genes: FTLP3, RPL21P2, AL356414.1.
- chr21:39,597,147–39,612,910, 1 gene (within-gene range 0–2): B3GALT5-AS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 8,813. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
